Surgical pathology report (de-identified scan), TCGA case TCGA-DT-5265, project TCGA-READ (Rectum Adenocarcinoma), tissue source site ILSBio, specimen TCGA-DT-5265-01A (Primary Tumor).

[page 1 of 3]
Pathology Form

Specimen Information

Collected by:

Date:

Time:

Preserved by:

Date:

Time:

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Rectum Tumor	5 x 4 x 3 cm		6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃ N ₀ M ₀ Stage: II			
Notes: Rectum node 1 (negative)			

[page 2 of 3]
Microscopic Description

Histological Pattern										
Cell Distribution			+	-	Structural Pattern			+	-	
Diffuse					Streaming					
Mosaic					Storiform					
Necrosis					Fibrosis					
Lymphocytic Infiltration					Palisading					
Vascular Invasion					Cystic Degeneration					
Clusterized					Bleeding					
Alveolar Formation					Myxoid Change					
Indian File					Psammoma/Calcification					

Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: Well Moderate Poor *X*

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		X		
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	

Nuclear Grade: 0 I II III

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Adenocarcinoma
(poorly differentiated) Grade: III

Comments:

[page 3 of 3]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			X	Streaming			
Mosaic		X		Storiform			
Necrosis			X	Fibrosis			
Lymphocytic Infiltration		X		Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized		X		Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		
Otherwise Specified: D, 80%, D2 75%, D3 65%, D4 75%											

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				X
Hyperchromatism			X	
Nucleolar Prominent			X	X
Multinucleated Giant Cell			X	X
Mitotic Activity				X
Nuclear Grade				X

Histological Diagnosis: Mucinous Adenocarcinoma, G-3

Comments: M. : Fatty tissue, not a lymph node: Rejected

Source: NCI Genomic Data Commons file df1b7a3c-098f-4e64-9489-6a7eb1771ecc (TCGA-DT-5265.C1E314D0-271B-411F-9BE8-6DB9C653A77A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).